Somatic mutation profile of tumor specimen TARGET-10-PATKWU-09A (aliquot TARGET-10-PATKWU-09A-01D) from TARGET case TARGET-10-PATKWU, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 13.2 years (4,834 days).
Specimen TARGET-10-PATKWU-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d8731ea3-4af1-4ade-b1cc-7a66d344f556.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PATKWU-10A (Blood Derived Normal), aliquot TARGET-10-PATKWU-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/25166803-4ff0-4a7b-b277-0bb0ecde569b

The open-access MAF lists 69 somatic variants for this specimen: 46 protein-altering or splice-affecting, 12 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 35, Silent 12, Intron 5, Nonsense Mutation 5, 5'Flank 2, 3'UTR 2, Frame Shift Ins 2, 5'UTR 1, RNA 1, Frame Shift Del 1, Splice Site 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CREBBP | c.4336C>T p.R1446C | Missense Mutation (SNP) | VAF 38/73 reads (52%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs398124146, COSV52113365, COSV52115600, COSV52116725; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- SMARCA4 | c.3404G>A p.R1135Q | Missense Mutation (SNP) | VAF 29/60 reads (48%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100758997, COSV60787834; called by muse, mutect2, varscan2
- ACADL | c.149G>A p.R50Q | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs758491059, COSV52052319; called by muse, mutect2, varscan2
- ADNP2 | c.1847C>T p.T616M | Missense Mutation (SNP) | VAF 39/85 reads (46%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.987); catalogued as COSV51536502; called by muse, mutect2, varscan2
- ANO4 | c.1558G>A p.V520M (on ENST00000392977 / NM_001286615.2; = p.V485M on NM_178826.4) | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.37); PolyPhen probably damaging (1); catalogued as rs773439481, COSV54587049; called by muse, varscan2
- ATP7B | c.2621C>T p.A874V | Missense Mutation (SNP) | VAF 49/91 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as rs121907994, CM980173, COSV54435550; ClinVar: conflicting interpretations of pathogenicity / pathogenic; called by muse, mutect2, varscan2
- C11orf58 | c.134T>C p.M45T | Missense Mutation (SNP) | VAF 35/58 reads (60%) | SIFT deleterious (0); PolyPhen benign (0.051); catalogued as COSV57178124; called by muse, mutect2, varscan2
- CCND2 | c.796C>T p.R266C | Missense Mutation (SNP) | VAF 40/89 reads (45%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.601); catalogued as rs1487732338, COSV54221791; called by muse, mutect2, varscan2
- CDR2L | c.384G>T p.E128D | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated (0.79); PolyPhen benign (0.053); catalogued as COSV100464285, COSV61500678; called by muse, mutect2, varscan2
- CPEB4 | c.1273C>T p.R425* | Nonsense Mutation (SNP) | VAF 20/56 reads (36%) | catalogued as COSV54169112; called by muse, mutect2, varscan2
- CPNE9 | c.317C>T p.A106V | Missense Mutation (SNP) | VAF 42/94 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs780866444, COSV56003392; called by muse, mutect2, varscan2
- DMRT3 | c.1033G>A p.D345N | Missense Mutation (SNP) | VAF 83/178 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.883); catalogued as rs746000511, COSV51902520; called by muse, mutect2
- DSCAML1 | c.3278G>A p.S1093N (on ENST00000321322; = p.S1033N on NM_020693.4) | Missense Mutation (SNP) | VAF 21/37 reads (57%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.984); catalogued as rs770118048, COSV58382846; called by muse, mutect2, varscan2
- EED | c.554A>C p.H185P | Missense Mutation (SNP) | VAF 15/29 reads (52%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.965); catalogued as COSV54553397; called by muse, mutect2, varscan2
- EED | c.826G>T p.E276* | Nonsense Mutation (SNP) | VAF 28/68 reads (41%) | catalogued as COSV54553414; called by muse, mutect2, varscan2
- EGLN3 | c.376C>T p.P126S | Missense Mutation (SNP) | VAF 30/120 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51654076; called by muse, mutect2, varscan2
- ELAVL3 | c.430C>T p.L144F | Missense Mutation (SNP) | VAF 32/72 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as COSV63645224; called by muse, mutect2, varscan2
- GNB5 | c.761_762insGAATAAAGCCCC p.F254delinsLNKAP (on ENST00000261837 / NM_016194.4; = p.F212delinsLNKAP on NM_006578.4 and 1 other RefSeq transcript) | In Frame Ins (INS) | VAF 21/45 reads (47%) | catalogued as COSV55897978; called by mutect2, pindel, varscan2
- H2BC10 | c.358A>G p.T120A | Missense Mutation (SNP) | VAF 32/67 reads (48%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.534); catalogued as COSV59952648; called by muse, mutect2, varscan2
- HNMT | c.38G>A p.G13E | Missense Mutation (SNP) | VAF 39/70 reads (56%) | SIFT tolerated (0.19); PolyPhen benign (0.101); catalogued as rs774154790, COSV54504540; called by muse, mutect2, varscan2
- KLF9 | c.62G>A p.R21H | Missense Mutation (SNP) | VAF 19/35 reads (54%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.939); catalogued as COSV65807357; called by muse, mutect2, varscan2
- LEF1 | c.416C>A p.S139* | Nonsense Mutation (SNP) | VAF 13/29 reads (45%) | catalogued as COSV54464243; called by muse, mutect2, varscan2
- LUC7L | c.131G>A p.C44Y | Missense Mutation (SNP) | VAF 29/69 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53456995; called by muse, mutect2, varscan2
- LZTS1 | c.980C>T p.A327V | Missense Mutation (SNP) | VAF 36/76 reads (47%) | SIFT tolerated (0.1); PolyPhen benign (0.035); catalogued as rs199711006, COSV56115938; called by muse, mutect2, varscan2
- MARK1 | c.1714G>A p.G572S | Missense Mutation (SNP) | VAF 3/50 reads (6%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs1158693975, COSV65065783; called by muse, mutect2
- MYH1 | c.5470C>T p.R1824C | Missense Mutation (SNP) | VAF 51/92 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs376061795; called by muse, mutect2, varscan2
- NOTCH1 | c.7541_7542del p.P2514Rfs*4 | Frame Shift Del (DEL) | VAF 28/83 reads (34%) | catalogued as rs763016003, COSV53024776; ClinVar: uncertain significance; called by mutect2, pindel, varscan2
- NOTCH1 | c.4297G>C p.G1433R | Missense Mutation (SNP) | VAF 55/114 reads (48%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV53032088; called by muse, mutect2, varscan2
- ORAI1 | c.550A>T p.T184S | Missense Mutation (SNP) | VAF 12/146 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.817); catalogued as COSV57490985; called by muse, mutect2
- PAPLN | c.1352G>T p.R451L (on ENST00000554301; = p.R424L on NM_173462.4) | Missense Mutation (SNP) | VAF 87/87 reads (100%) | SIFT tolerated (0.18); PolyPhen benign (0.012); catalogued as COSV53713724; called by muse, mutect2, varscan2
- PHF6 | c.644G>T p.C215F (on ENST00000332070 / NM_032458.3; = p.C216F on NM_032335.3) | Missense Mutation (SNP) | VAF 30/31 reads (97%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV59699867; called by muse, mutect2, varscan2
- PLG | c.740C>A p.T247N | Missense Mutation (SNP) | VAF 46/90 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV51980990; called by muse, mutect2
- PTH2R | c.379C>A p.R127S | Missense Mutation (SNP) | VAF 28/68 reads (41%) | SIFT tolerated (0.31); PolyPhen benign (0.039); catalogued as COSV55914177; called by muse, mutect2, varscan2
- PTPN5 | c.886G>A p.D296N | Missense Mutation (SNP) | VAF 30/75 reads (40%) | SIFT tolerated (0.25); PolyPhen benign (0.021); catalogued as rs1411732635, COSV62124941; called by muse, mutect2, varscan2
- RALGAPA1 | c.5629G>T p.E1877* | Nonsense Mutation (SNP) | VAF 12/41 reads (29%) | catalogued as COSV51877465; called by muse, mutect2, varscan2
- RHBDF1 | c.713G>A p.R238H | Missense Mutation (SNP) | VAF 41/68 reads (60%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as rs879417615, COSV51953685; called by muse, mutect2, varscan2
- SESN3 | c.144+2T>G p.X48_splice | Splice Site (SNP) | VAF 21/39 reads (54%) | catalogued as COSV53583473; called by muse, mutect2, varscan2
- TAS2R31 | c.770A>G p.N257S | Missense Mutation (SNP) | VAF 128/289 reads (44%) | SIFT tolerated (0.16); PolyPhen benign (0.17); catalogued as COSV66829942; called by muse, varscan2
- TENM2 | c.6796G>A p.D2266N (on ENST00000518659 / NM_001122679.2; = p.D2027N on NM_001080428.3) | Missense Mutation (SNP) | VAF 30/71 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.26); catalogued as rs780306599, COSV69123621; called by muse, mutect2, varscan2
- VN1R4 | c.757C>G p.Q253E | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.209); catalogued as COSV60804718, COSV60805025; called by muse, mutect2, varscan2
- WASHC5 | c.673G>A p.V225I | Missense Mutation (SNP) | VAF 48/123 reads (39%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.956); catalogued as COSV59194345; called by muse, mutect2, varscan2
- ZNF268 | c.886C>T p.Q296* | Nonsense Mutation (SNP) | VAF 54/119 reads (45%) | catalogued as COSV57212021; called by muse, mutect2, varscan2
- ZNF622 | c.730C>A p.P244T | Missense Mutation (SNP) | VAF 41/101 reads (41%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV58073579, COSV58074185; called by muse, mutect2, varscan2
- ABR | c.534C>A p.A178= (on ENST00000302538 / NM_021962.5; = p.A141= on NM_001092.5) | Splice Region (SNP) | VAF 19/44 reads (43%) | called by muse, mutect2, varscan2
- ANKRD11 | c.3835dup p.S1279Kfs*4 | Frame Shift Ins (INS) | VAF 50/117 reads (43%) | called by mutect2, pindel, varscan2
- DYNC1H1 | c.1165dup p.S389Kfs*11 | Frame Shift Ins (INS) | VAF 110/219 reads (50%) | called by mutect2, pindel, varscan2
- CCDC17 | c.384C>T p.S128= | Silent (SNP) | VAF 22/49 reads (45%) | catalogued as COSV51966883; called by muse, mutect2, varscan2
- CCT8L2 | c.162C>T p.H54= | Silent (SNP) | VAF 17/38 reads (45%) | catalogued as rs191641638, COSV63463749; called by muse, mutect2, varscan2
- ENPEP | c.1926G>A p.A642= | Silent (SNP) | VAF 11/111 reads (10%) | catalogued as rs757912646, COSV99487955; called by muse, mutect2, varscan2
- F11 | c.147C>A p.V49= | Silent (SNP) | VAF 30/63 reads (48%) | called by muse, mutect2, varscan2
- GABRG1 | c.40C>T p.L14= | Silent (SNP) | VAF 59/101 reads (58%) | catalogued as rs761944186; called by muse, mutect2, varscan2
- KCNJ12 | c.303C>A p.I101= | Silent (SNP) | VAF 44/119 reads (37%) | catalogued as rs1252165259; called by muse, mutect2, varscan2
- MICAL3 | c.4677G>A p.P1559= | Silent (SNP) | VAF 9/78 reads (12%) | catalogued as rs370464455; called by muse, mutect2, varscan2
- MYO9B | c.3474C>T p.H1158= | Silent (SNP) | VAF 40/93 reads (43%) | catalogued as rs754108601; called by muse, mutect2, varscan2
- TRIM3 | c.2088C>T p.F696= | Silent (SNP) | VAF 55/94 reads (59%) | catalogued as rs370951694, COSV61984922; called by muse, mutect2, varscan2
- VPS51 | c.499C>T p.L167= | Silent (SNP) | VAF 37/63 reads (59%) | catalogued as rs754553722; called by muse, mutect2, varscan2
- ZNF516 | c.2796G>A p.T932= | Silent (SNP) | VAF 44/81 reads (54%) | catalogued as rs368519568; called by muse, mutect2, varscan2
- ZNF516 | c.822C>T p.F274= | Silent (SNP) | VAF 25/46 reads (54%) | catalogued as COSV71587040; called by muse, mutect2, varscan2
- BAX | c.474+36C>T | Intron (SNP) | VAF 16/26 reads (62%) | catalogued as rs765013477; called by muse, varscan2
- BLOC1S5-TXNDC5 | c.372+39070C>A | Intron (SNP) | VAF 70/140 reads (50%) | called by muse, mutect2, varscan2
- CA3 | c.*5G>T | 3'UTR (SNP) | VAF 24/58 reads (41%) | called by muse, mutect2, varscan2
- CSNK1E | c.886-2121G>A | Intron (SNP) | VAF 22/38 reads (58%) | catalogued as rs1368299541; called by muse, mutect2, varscan2
- DPP10 | c.61-147012C>T | Intron (SNP) | VAF 12/27 reads (44%) | called by muse, mutect2, varscan2
- GLTPP1 | chr11:18188955 G>A | 5'Flank (SNP) | VAF 3/29 reads (10%) | catalogued as rs939418070; called by muse, mutect2
- LINC01591 | n.418G>A | RNA (SNP) | VAF 41/79 reads (52%) | catalogued as rs181295694; called by muse, mutect2, varscan2
- LMLN | c.1232+3753G>T | Intron (SNP) | VAF 31/63 reads (49%) | catalogued as COSV57598286; called by muse, mutect2, varscan2
- RLF | c.-13G>A | 5'UTR (SNP) | VAF 23/34 reads (68%) | called by muse, mutect2, varscan2
- RNU1-6P | chr1:16536134 C>T | 5'Flank (SNP) | VAF 15/138 reads (11%) | called by muse, mutect2, varscan2
- VPS53 | c.*13G>T | 3'UTR (SNP) | VAF 56/111 reads (50%) | called by muse, mutect2, varscan2
